Surgical pathology report (de-identified scan), TCGA case TCGA-DW-7842, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site NCI Urologic Oncology Branch, specimen TCGA-DW-7842-01A (Primary Tumor).

[page 1 of 5]
DIAGNOSIS:

1. Adrenal gland, left, mass, adrenalectomy (1FS): Adrenal adenoma.
2. Kidney, left, tumor #1, resection: Renal cell carcinoma, papillary type I.
3. Kidney, left, tumor #2, resection: Renal cell carcinoma, papillary type I with incipient lesions scattered throughout the renal parenchyma. The inked margin is free of tumor.
4. Kidney, left, tumor #3 and #4, resection: Renal cell carcinoma, papillary type I with areas of clear cell differentiation. Tumor approaches the black-inked margin.
5. Kidney, left, base of margin for tumor #3 and #4, resection: Renal parenchyma with incipient lesions and calcifications.
6. Kidney, left, base of margin for tumor #3 and #4 (final), resection: Renal parenchyma.
7. Kidney, left, tumor #5, resection: Renal cell carcinoma, papillary type I.
8. Kidney, left, tumor #6, resection: Renal cell carcinoma, papillary type I with incipient lesions.
9. Kidney, left, tumor #7, resection: Renal cell carcinoma, papillary type I.
10. Kidney, left, tumor #8, resection: Renal cell carcinoma, papillary type I.
11. Kidney, left, tumor #9, resection: Renal cell carcinoma, papillary type I.
12. Kidney, left, base of tumor #2, resection: Renal cell carcinoma, papillary type I.

[page 2 of 5]
13. Kidney, left, tumor #2, resection: Renal cell carcinoma, papillary type I with incipient lesions.

Immunoperoxidase and in-situ hybridization tests performed here and used for diagnosis were developed and their performance characteristics determined by the [REDACTED]. They have not been cleared or approved by the U.S. Food and Drug Administration. The FDA has also determined that such clearance or approval is not necessary. This laboratory is certified under the Clinical Laboratory Improvement Amendments of [REDACTED] (CLIA) as qualified to perform high complexity clinical laboratory testing.

CLINICAL INFORMATION:

Allocate Order to [REDACTED]

Brief Clinical History: [REDACTED] male with hereditary papillary type 1 renal cell cancer.

PROCEDURE: Left adrenalectomy and left partial nephrectomy.

SPECIMENS SUBMITTED: 1. ADRENAL MASS, LEFT, (1FS)

2. TUMOR, Left kidney # 1
3. TUMOR, Left kidney # 2
4. TUMOR, Left kidney # 3 & #4
5. TUMOR, Left kidney base of margin 3&4
6. TUMOR, Left kidney base margin 3&4 # 2 final
7. TUMOR, Left kidney tumor # 5
8. TUMOR, Left kidney # 6
9. TUMOR, Left kidney # 7
10. TUMOR, Left kidney # 8
11. TUMOR, Left kidney # 9
12. TUMOR, Left kidney base # 7
13. TUMOR, Left kidney # 10

INTRAOPERATIVE CONSULTATION:

1FS: "Left adrenal mass"

1FS Diagnosis: Adrenal cortical tumor.

The above findings were communicated to the clinical team with [REDACTED]

GROSS DESCRIPTION: Received fresh from the OR are 13 separate specimens, labeled with the patient's name, medical record number, and further specified as follows:

1. "Left adrenal mass" consisting of a yellow encapsulated nodule and associated fat measuring in aggregate 5.0 x 4.0 x 3.0 cm and weighing 36.2 grams. The capsule was focally disrupted when received. The specimen is sectioned to reveal golden yellow, nodular cut surface with focal hemorrhage. A representative section from the center of nodule is frozen as "1FS." Gross pictures are taken. The specimen is inked black and placed into

Patient Identification

[page 3 of 5]
[REDACTED]

formalin for permanent processing. Approximately 2.0 x 1.5 x 0.5 cm of tissue is procured for [REDACTED]. The procurement was performed and documented by [REDACTED] on [REDACTED] at [REDACTED]. Received in Surgical Pathology is a specimen matching the above description. The specimen is serially sectioned and representative sections are submitted into cassettes labeled [REDACTED] #1A-F. Additionally received is a green cassette labeled [REDACTED] 1FS, the contents of which are entirely transferred to an orange cassette labeled [REDACTED] 1FS. The remaining tissue is returned to formalin.

2. "Tumor #1 left kidney" is a portion of kidney, overall 4.8 x 4 x 3.6 cm. It is largely comprised of a red-orange tumor (4.7 cm in greatest dimension) with a clear margin of kidney parenchyma (0.5 cm in maximum thickness). It is bisected by [REDACTED] in the OR, revealing a variegated red-orange friable cut surface with approximately 20% of hemorrhage and necrosis. Gross photographs are taken. Core biopsies are obtained by [REDACTED] for their research. Approximately 35% of what appears to be viable tumor and approximately 0.5 x 0.5 x 0.3 cm of normal-appearing kidney parenchyma are procured by [REDACTED] in the OR for the [REDACTED] lab and documented by [REDACTED] on [REDACTED] at [REDACTED]. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Surgical Pathology is a specimen matching the above description. The specimen is oriented with [REDACTED] and the portion that she indicates as "surgical margin" is inked in black. Serial sections are taken through this inked margin and are entirely submitted in cassettes labeled [REDACTED] #2A-L. A cross section of the tumor surface is submitted in cassette [REDACTED]. The remainder of the tissue is returned for formalin.

3. "Tumor #2 left kidney" is a portion of kidney, overall 3.5 x 3 x 3 cm. It is largely comprised of a yellow tumor (3.5 cm in greatest dimension) with a portion in which normal kidney kidney parenchyma covers it. Where the tumor protrudes, the tissue is inked black. [REDACTED] are informed of a gross positive tumor margin by [REDACTED] in the OR on [REDACTED]. Core biopsies are obtained by [REDACTED] for their research. The tumor is bisected revealing a yellow soft and slightly myxoid cut surface. Gross photographs are taken. Approximately 35% of the viable-appearing tumor and approximately 0.2 x 0.2 x 0.2 cm of normal-appearing kidney parenchyma are procured by [REDACTED] and documented by [REDACTED]. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Surgical Pathology is a specimen matching the above description. The specimen is oriented with [REDACTED] the portion inked in black which represents the margin of resection is serially sectioned and entirely submitted in cassettes labeled [REDACTED]. The remaining tissue is returned to formalin.

4. "Left kidney tumor #3 and #4" is a portion of kidney, overall 5 x 4 x 2.7 cm. It consists of an aggregate of abutting tumor nodules with a rim of kidney parenchyma. The nodule identified by [REDACTED] as nodule #3 (2 cm in greatest dimension) is inked blue by [REDACTED]. The nodule identified by [REDACTED] as nodule #4 (2.7 cm in greatest dimension) is inked orange. The surgical margin is identified and inked black. In the OR, [REDACTED] of a positive gross margin. Nodule #3 has a viable-appearing homogeneous yellow soft cut surface. Nodule #4 has a mostly friable red-yellow variegated and hemorrhagic, necrotic cut surface. Gross photographs are taken. A portion of the more viable-appearing nodule (nodule #3) is minced and submitted in glutaraldehyde for [REDACTED] studies, per [REDACTED] request. Core biopsies are obtained by [REDACTED].

Patient Identification

[page 4 of 5]
[REDACTED]

[REDACTED] tumor #3 and #4 for the [REDACTED] lab. Approximately 35% of tissue from nodule #3 and 20% of tissue from nodule #4 are procured for [REDACTED] lab by [REDACTED] and documented by [REDACTED]. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Surgical Pathology is a specimen matching the above description. The black inked portion of the specimen which corresponds to the surgical margin is serially sectioned and entirely submitted in cassettes [REDACTED]. Representative sections of the tumor inked in blue corresponding to tumor #3 are submitted in cassettes [REDACTED]. Representative sections of the tumor inked in orange corresponding to tumor #4 are submitted in cassettes [REDACTED]. The remaining tissue is returned to formalin.

5. Received fresh is a specimen labeled with the patient's name, medical record number, and further specified "base margin tumor 3 + 4 left kidney" consisting of a single tan-yellow soft tissue fragment measuring 0.8 x 0.3 x 0.2 cm which is filtered into a biopsy specimen bag and entirely submitted in cassette [REDACTED].

6. "Left kidney base margin 3 + 4 #2 final" consisting of a single yellow-tan soft tissue fragment measuring 0.7 x 0.4 x 0.2 cm which is filtered into a biopsy specimen bag and entirely submitted in a cassette labeled [REDACTED] #6.

7. "Left kidney tumor #5" consisting of a single yellow-tan soft tissue fragment measuring 0.8 x 0.6 x 0.5 cm which is bisected and entirely submitted in a cassette labeled [REDACTED].

8. "Left kidney tumor #6" consisting of a single yellow-tan nodule measuring 0.8 x 0.6 x 0.5 cm which is bisected and entirely submitted in a cassette labeled [REDACTED] #8.

9. "Left kidney tumor #7" is a portion of kidney, overall 1.3 x 1.3 x 1 cm. It is comprised mostly of a well-circumscribed, spherical yellow tumor (1 x 0.8 x 0.7 cm). The external surface is inked black by [REDACTED] in the [REDACTED] of a possible grossly positive margin. The tumor is bisected revealing a homogeneous yellow, soft cut surface. Approximately 30% of the tumor is procured for [REDACTED] lab by [REDACTED] in the OR and documented by [REDACTED]. Gross photographs are taken. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing. Received in Surgical Pathology is a specimen matching the above description measuring 1.0 x 1.0 x 0.6 cm. It is bisected and entirely submitted in a cassette labeled [REDACTED] #9.

10. "Left kidney tumor #8" consisting of a single yellow-tan soft tissue fragment measuring 0.9 x 0.5 x 0.3 cm which is entirely submitted in a cassette labeled [REDACTED] #10.

11. "Left kidney tumor #9" consisting of a single yellow-tan soft tissue fragment measuring 0.6 x 0.5 x 0.4 cm which is entirely submitted in a cassette labeled [REDACTED] #11.

12. "Base of tumor #7 left kidney" consisting of 3 distinct yellow-tan soft tissue fragments measuring in aggregate 1.0 x 0.8 x 0.5 cm which are entirely submitted in a cassette labeled [REDACTED] #12.

[page 5 of 5]
13. "Left kidney tumor #10" is comprised of five tumor fragments ranging from 0.5 to 1.7 cm in greatest dimensions and in the aggregate 1.7 x 1 x 0.3 cm. There is a separately received irregularly-shaped portion of normal-appearing kidney parenchyma (2.3 x 1.2 x 0.4 cm). Gross photographs are taken. Margin assessment is not requested, per [REDACTED] on this specimen. Approximately 30% of each of the tumor fragments and 10% of the normal-appearing kidney parenchyma are procured for [REDACTED] lab in the OR by [REDACTED]. The remainder of the specimen is placed into formalin and submitted to Pathology for permanent processing.

[REDACTED]

[REDACTED]

Patient Identification

Source: NCI Genomic Data Commons file 7a2b1ff8-ed98-41eb-a389-7a2fb6225068 (TCGA-DW-7842.AE062038-A824-4F59-A8C6-BDA63F439870.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).